Somatic mutation profile of tumor specimen C3N-04152-01 (aliquot CPT0223970006) from CPTAC case C3N-04152, project CPTAC-3 (Oropharynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Oropharynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,705 days).
Specimen C3N-04152-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Oropharynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d37c671-2691-421f-b3c7-4ae38e7bcc0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04152-71 (Blood Derived Normal), aliquot CPT0224090002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f52d74a-52fd-4cc0-949a-73d19e036454

The open-access MAF lists 99 somatic variants for this specimen: 60 protein-altering or splice-affecting, 32 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 32, Splice Region 3, 3'UTR 2, RNA 2, 5'UTR 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 177/290 reads (61%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMPD2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as rs768283469, COSV56650446; called by muse, mutect2, varscan2
- ARID1A | c.3221G>A p.R1074Q | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV100251177, COSV61372213; called by muse, mutect2, varscan2
- CASP8AP2 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1480474009; called by muse, mutect2, varscan2
- CDC42SE2 | c.197A>G p.Y66C | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs771972972; called by muse, mutect2, varscan2
- DENND4B | c.1385C>A p.A462E | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63409449; called by muse, mutect2, varscan2
- ERICH3 | c.1300G>C p.E434Q | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV58599526, COSV58616152; called by muse, mutect2
- EVPL | c.3740C>T p.T1247M | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs145713300; called by muse, mutect2, varscan2
- IGSF6 | c.28G>A p.A10T | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs780421744, COSV51679319; called by muse, mutect2, varscan2
- KLHDC9 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1298035727; called by muse, mutect2, varscan2
- MUC4 | c.12904C>T p.R4302C (on ENST00000463781 / NM_018406.7; = p.R66C on NM_004532.6) | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs759653732, COSV100204198; called by muse, mutect2, varscan2
- NTN4 | c.1148G>A p.R383Q | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.253); catalogued as rs776649804, COSV59217232; called by muse, mutect2, varscan2
- NYAP2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 109/241 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs760861891, COSV56012875; called by muse, mutect2, varscan2
- PCLO | c.8431G>A p.E2811K | Missense Mutation (SNP) | VAF 104/247 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV61623653; called by muse, mutect2, varscan2
- PLAAT2 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 78/203 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as rs1453210130; called by muse, mutect2, varscan2
- PLCB4 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 59/192 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1312728965, COSV99595366; called by muse, mutect2, varscan2
- RIMS2 | c.2233A>G p.I745V (on ENST00000666250 / NM_001348490.2; = p.I553V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51658077; called by muse, mutect2
- RPL5 | c.705+8A>G | Splice Region (SNP) | VAF 48/135 reads (36%) | catalogued as rs748107295; called by muse, mutect2, varscan2
- RYR1 | c.12785_12790dup p.D4262_E4263dup | In Frame Ins (INS) | VAF 100/338 reads (30%) | catalogued as rs746833347; called by mutect2, varscan2
- SHANK2 | c.4168C>T p.R1390C | Missense Mutation (SNP) | VAF 63/1258 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs371473462; called by muse, mutect2
- SIGLEC12 | c.374G>C p.R125T | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs762995704; called by muse, mutect2, varscan2
- TRMT2B | c.1334C>T p.T445M | Missense Mutation (SNP) | VAF 47/79 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs768238349, COSV58618782; called by muse, mutect2, varscan2
- TTN | c.99170G>A p.R33057Q (on ENST00000591111; = p.R25633Q on NM_003319.4) | Missense Mutation (SNP) | VAF 36/106 reads (34%) | PolyPhen benign (0.23); catalogued as rs757940030; ClinVar: likely benign; called by muse, mutect2, varscan2
- TULP4 | c.1208G>A p.R403H | Missense Mutation (SNP) | VAF 37/298 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs1562584024; called by muse, mutect2, varscan2
- UNK | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759505790; called by muse, mutect2, varscan2
- ADCY10 | c.4635dup p.N1546Efs*20 | Frame Shift Ins (INS) | VAF 190/600 reads (32%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.671C>A p.A224D | Missense Mutation (SNP) | VAF 168/466 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CAPRIN2 | c.2026C>T p.L676F | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- COL12A1 | c.7015T>A p.F2339I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DCHS1 | c.746A>C p.N249T | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DNMT3B | c.1690T>C p.Y564H | Missense Mutation (SNP) | VAF 22/592 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- EIF3H | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2
- FLNC | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 168/279 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- GCC2 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GOLGB1 | c.8400G>T p.L2800F | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GRIN2D | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 78/213 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HELZ2 | c.5752C>T p.R1918W (on ENST00000467148 / NM_001037335.2; = p.R1349W on NM_033405.3) | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- MAST3 | c.2117A>G p.K706R | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- METTL27 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 6/129 reads (5%) | SIFT tolerated (0.48); PolyPhen benign (0.012); called by muse, mutect2
- MIS18BP1 | c.2300_2312del p.S767Cfs*33 | Frame Shift Del (DEL) | VAF 160/330 reads (48%) | called by mutect2, pindel, varscan2
- MYOM1 | c.2339C>G p.S780C | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NLRP3 | c.834C>G p.C278W | Missense Mutation (SNP) | VAF 87/154 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PAXBP1 | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIEZO2 | c.5149G>A p.E1717K | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- PIP4P2 | c.379C>A p.L127I | Missense Mutation (SNP) | VAF 21/148 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PLBD2 | c.1158C>A p.F386L | Missense Mutation (SNP) | VAF 72/257 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PLEKHG2 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- RFX4 | c.1633+6G>C | Splice Region (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- RORC | c.1095G>T p.M365I | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RTTN | c.1438G>C p.A480P | Missense Mutation (SNP) | VAF 67/148 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- SLFN11 | c.1262G>T p.R421I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- SMG1 | c.9398C>A p.S3133Y | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- SMG1 | c.8374C>T p.Q2792* | Nonsense Mutation (SNP) | VAF 12/316 reads (4%) | called by muse, mutect2
- TAS2R38 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TEX35 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- THRA | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TINF2 | c.1061+5G>C | Splice Region (SNP) | VAF 189/761 reads (25%) | called by muse, mutect2, varscan2
- TTC39A | c.497C>G p.P166R (on ENST00000447632 / NM_001297665.1; = p.P165R on NM_001297662.2) | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USF2 | c.685A>G p.R229G | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- USF3 | c.3607G>C p.E1203Q | Missense Mutation (SNP) | VAF 69/215 reads (32%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1782G>A p.E594= | Silent (SNP) | VAF 8/183 reads (4%) | called by muse, mutect2
- ASH1L | c.2298C>T p.P766= | Silent (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- CABP5 | c.249T>C p.R83= | Silent (SNP) | VAF 9/154 reads (6%) | called by muse, mutect2
- CACNA1C | c.1341C>A p.I447= | Silent (SNP) | VAF 80/206 reads (39%) | called by muse, mutect2, varscan2
- CATSPERD | c.1749G>A p.K583= | Silent (SNP) | VAF 61/312 reads (20%) | catalogued as rs57970792; called by muse, mutect2, varscan2
- CCDC92 | c.897C>A p.T299= | Silent (SNP) | VAF 68/183 reads (37%) | called by muse, mutect2, varscan2
- CEACAM21 | c.558C>A p.V186= | Silent (SNP) | VAF 95/343 reads (28%) | called by muse, mutect2, varscan2
- CHD9 | c.6657C>T p.S2219= | Silent (SNP) | VAF 29/83 reads (35%) | catalogued as rs1377282342, COSV54607120; called by muse, mutect2, varscan2
- CLEC18B | c.909C>T p.D303= | Silent (SNP) | VAF 69/581 reads (12%) | called by muse, mutect2, varscan2
- CMAS | c.1164C>T p.G388= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as rs765385723, COSV57556078; called by muse, mutect2, varscan2
- CRISP2 | c.486A>G p.K162= | Silent (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- CTIF | c.1320C>T p.L440= | Silent (SNP) | VAF 12/173 reads (7%) | catalogued as COSV56482184; called by muse, mutect2
- FAM171A2 | c.1776G>A p.P592= | Silent (SNP) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- FSHR | c.537G>A p.K179= | Silent (SNP) | VAF 103/326 reads (32%) | called by muse, mutect2, varscan2
- GPR132 | c.13C>T p.L5= | Silent (SNP) | VAF 29/101 reads (29%) | called by muse, mutect2, varscan2
- KHDC3L | c.393C>A p.A131= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- MAP1S | c.1038G>A p.S346= | Silent (SNP) | VAF 22/746 reads (3%) | catalogued as rs1345980554; called by muse, mutect2
- MCIDAS | c.78G>C p.P26= | Silent (SNP) | VAF 74/163 reads (45%) | called by muse, mutect2, varscan2
- MLPH | c.1698T>C p.D566= | Silent (SNP) | VAF 81/250 reads (32%) | called by muse, mutect2, varscan2
- NAV2 | c.6180G>T p.R2060= (on ENST00000396087 / NM_001244963.2; = p.R2001= on NM_145117.5) | Silent (SNP) | VAF 54/159 reads (34%) | called by muse, mutect2, varscan2
- NOD2 | c.1515G>T p.G505= | Silent (SNP) | VAF 50/167 reads (30%) | catalogued as rs769034739, COSV56048206; called by muse, varscan2
- OR10X1 | c.762C>T p.F254= | Silent (SNP) | VAF 10/153 reads (7%) | catalogued as rs1428681863, COSV63767348; called by muse, mutect2
- POMGNT2 | c.162G>A p.P54= | Silent (SNP) | VAF 87/142 reads (61%) | catalogued as rs755111895, COSV60952586; called by muse, mutect2, varscan2
- PRKG2 | c.1851A>G p.V617= | Silent (SNP) | VAF 130/352 reads (37%) | called by muse, mutect2, varscan2
- ROBO3 | c.843G>A p.V281= | Silent (SNP) | VAF 93/180 reads (52%) | called by muse, mutect2, varscan2
- SEPTIN8 | c.1431G>A p.T477= | Silent (SNP) | VAF 241/385 reads (63%) | catalogued as rs756694987; called by muse, mutect2, varscan2
- SLC23A2 | c.1122C>T p.T374= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs768685613; called by muse, mutect2
- SNAI3 | c.430C>A p.R144= | Silent (SNP) | VAF 62/199 reads (31%) | called by muse, mutect2, varscan2
- SPATA2 | c.1254G>A p.S418= | Silent (SNP) | VAF 71/207 reads (34%) | catalogued as rs762017853; called by muse, mutect2, varscan2
- STARD9 | c.8181A>C p.A2727= | Silent (SNP) | VAF 94/265 reads (35%) | called by muse, mutect2, varscan2
- TMEM150B | c.690G>A p.P230= | Silent (SNP) | VAF 35/89 reads (39%) | catalogued as rs929546497, COSV100442359; called by muse, mutect2, varscan2
- TXLNA | c.513G>A p.E171= | Silent (SNP) | VAF 27/69 reads (39%) | called by muse, mutect2, varscan2
- AC114741.1 | n.291C>T | RNA (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+3824C>A | Intron (SNP) | VAF 57/178 reads (32%) | catalogued as rs1564972764; called by muse, mutect2, varscan2
- CES4A | c.-27C>A | 5'UTR (SNP) | VAF 71/197 reads (36%) | called by muse, mutect2, varscan2
- CSGALNACT1 | c.*233G>A | 3'UTR (SNP) | VAF 53/95 reads (56%) | called by muse, mutect2, varscan2
- FTH1 | c.-26G>A | 5'UTR (SNP) | VAF 182/483 reads (38%) | catalogued as rs10897188; called by muse, mutect2, varscan2
- HLA-L | n.944G>A | RNA (SNP) | VAF 46/144 reads (32%) | catalogued as rs747299344; called by muse, mutect2
- TTC24 | c.*4C>T | 3'UTR (SNP) | VAF 68/161 reads (42%) | called by muse, mutect2, varscan2
